TARGET case TARGET-15-SJMPAL012417 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7e60e21-3dba-430d-a7a5-aa17f4c2b533

Demographics
Sex at birth: male; Age at index: 11 years; Vital status: Dead; Days to death: 53 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.2 years (4,108 days); Year of diagnosis: 1998; Days to last follow up: 53 days.

Follow-up (1 entry)
- Days to follow up: 53 days; Event-free: no event (relapse, second malignancy or death) recorded through day 53; Year of follow up: 1998.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 0.5 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL012417-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 53
- Protocol: St. Jude
- WBC at Diagnosis: 0.5
- Karyotype: 46,XY,del(12)(p11.2p13)[16]/46,XY[4]
- WHO ALAL Classification: NOS (T/B/M)
- WHO Dx: NOS (T/B/M)
